Somatic mutation profile of tumor specimen TARGET-10-PARSTB-09A (aliquot TARGET-10-PARSTB-09A-01D) from TARGET case TARGET-10-PARSTB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.4 years (5,638 days).
Specimen TARGET-10-PARSTB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df3b808d-0a52-49b0-94b9-b0ee35b89625.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARSTB-10A (Blood Derived Normal), aliquot TARGET-10-PARSTB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c09fcdc8-cd5b-445c-b5ae-dcb4718a207a

The open-access MAF lists 28 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 5, Silent 5, Nonsense Mutation 3, 3'UTR 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHF6 | c.673C>T p.R225* (on ENST00000332070 / NM_032458.3; = p.R226* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as rs1556018932, COSV59699600; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.3514C>T p.Q1172* | Nonsense Mutation (SNP) | VAF 6/137 reads (4%) | catalogued as COSV61371253; called by muse, mutect2
- ARID1A | c.6746C>A p.S2249* | Nonsense Mutation (SNP) | VAF 14/152 reads (9%) | catalogued as COSV61376855, COSV61377034; called by muse, mutect2
- EPHA8 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs202015824, COSV51267123; called by muse, mutect2, varscan2
- ISLR2 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs1567161734; called by muse, mutect2, varscan2
- TBX18 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1380473486; called by muse, mutect2, varscan2
- TTN | c.10013A>G p.Q3338R (on ENST00000591111; = p.Q3292R on NM_003319.4) | Missense Mutation (SNP) | VAF 8/139 reads (6%) | PolyPhen benign (0.058); catalogued as COSV100634355; called by muse, mutect2
- CAD | c.4829T>C p.V1610A | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IL18RAP | c.1315C>A p.P439T | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITFG2 | c.274_275insGCCGT p.L92Cfs*6 | Frame Shift Ins (INS) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- RBMXL3 | c.1700G>T p.C567F | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- SCN3A | c.3310C>T p.P1104S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SLC5A8 | c.274T>C p.Y92H | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SOBP | c.860C>A p.A287E | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.738); called by muse, mutect2
- SWT1 | c.1973C>A p.A658D | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- VSNL1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2
- ABHD4 | c.394C>A p.R132= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as rs949135495, COSV99360557; called by muse, mutect2, varscan2
- ADAM28 | c.462A>G p.A154= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- ANAPC2 | c.2412G>A p.R804= | Silent (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- APIP | c.609A>G p.T203= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1306058668; called by muse, mutect2, varscan2
- RPS6KA6 | c.567G>T p.L189= | Silent (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- APOC2 | c.216-74A>C | Intron (SNP) | VAF 6/14 reads (43%) | catalogued as rs111893784; called by muse, varscan2
- FCHSD1 | c.1951+453del | Intron (DEL) | VAF 3/38 reads (8%) | catalogued as rs767126877; called by pindel, varscan2
- LMBRD2 | c.175-152C>A | Intron (SNP) | VAF 10/14 reads (71%) | called by muse, varscan2
- OR2H2 | c.*22T>G | 3'UTR (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2
- OSBPL2 | c.872+11G>T | Intron (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2, varscan2
- PTPN21 | c.-28G>T | 5'UTR (SNP) | VAF 7/44 reads (16%) | catalogued as COSV60851738; called by muse, mutect2, varscan2
- RHBG | c.1112+10C>T | Intron (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2
